Somatic mutation profile of tumor specimen TCGA-AA-3819-01A (aliquot TCGA-AA-3819-01A-01W-0900-09) from TCGA case TCGA-AA-3819, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 41.8 years (15,280 days).
Specimen TCGA-AA-3819-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dac64272-8c63-4dde-bac1-5ce5ea9252d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3819-10A (Blood Derived Normal), aliquot TCGA-AA-3819-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5843bc08-274a-42ff-b344-104efdbe5df7

The open-access MAF lists 198 somatic variants for this specimen: 153 protein-altering or splice-affecting, 40 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 40, Nonsense Mutation 10, Frame Shift Del 5, Splice Region 3, Splice Site 3, RNA 2, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.5178-1G>A p.X1726_splice | Splice Site (SNP) | VAF 46/121 reads (38%) | catalogued as rs1555105579, COSV53737155, COSV99588039; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.378C>G p.N126K | Missense Mutation (SNP) | VAF 39/162 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV57246407, COSV57258957; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 77/231 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASS | c.461C>A p.A154D | Missense Mutation (SNP) | VAF 146/461 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV62790065, COSV62790241; called by muse, varscan2
- ABCA5 | c.4804C>T p.Q1602* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99288095; called by muse, mutect2, varscan2
- AC006059.2 | c.1125G>A p.M375I | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV59607205; called by muse, mutect2, varscan2
- ACSL4 | c.1879G>A p.A627T (on ENST00000340800 / NM_022977.2; = p.A586T on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/342 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV61614636; called by muse, mutect2, varscan2
- ACSS3 | c.626G>T p.S209I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV54092247; called by muse, mutect2, varscan2
- ADGRE1 | c.433C>A p.H145N | Missense Mutation (SNP) | VAF 91/240 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.022); catalogued as COSV51676228; called by muse, mutect2, varscan2
- ADGRV1 | c.12256C>T p.P4086S | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67986490; called by muse, mutect2, varscan2
- AGO4 | c.1024T>A p.C342S | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV64617304; called by muse, mutect2, varscan2
- ALS2CL | c.1234C>A p.H412N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV59671749; called by muse, mutect2, varscan2
- ANKRD29 | c.347T>G p.L116R | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99409072; called by muse, varscan2
- AP1M1 | c.463A>T p.N155Y | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52226827, COSV99358488; called by muse, mutect2, varscan2
- AP1S2 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV57065143; called by muse, mutect2, varscan2
- APCDD1L | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 69/101 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371147444; called by muse, mutect2, varscan2
- ATG2B | c.3479C>A p.S1160* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV55890642; called by muse, mutect2, varscan2
- ATG4D | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs748483612, COSV57264161; called by muse, mutect2, varscan2
- ATM | c.7305C>G p.N2435K | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1160508407, CM092587, COSV53746307, COSV53748099; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCL9L | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV52689388; called by muse, mutect2, varscan2
- BOC | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV56352012; called by muse, mutect2, varscan2
- BPIFB4 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64951329; called by muse, mutect2, varscan2
- BPTF | c.3122A>T p.H1041L | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV58838174; called by muse, mutect2, varscan2
- C20orf85 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV64519425; called by muse, mutect2, varscan2
- CACNA1E | c.983G>T p.W328L | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62396280, COSV62398548; called by muse, mutect2, varscan2
- CCDC8 | c.1577G>C p.R526T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as COSV56773618; called by muse, mutect2, varscan2
- CD1E | c.918del p.L308Sfs*3 | Frame Shift Del (DEL) | VAF 33/98 reads (34%) | catalogued as COSV100936954, COSV63770816, COSV63771236; called by mutect2, pindel, varscan2
- CELSR1 | c.5758G>T p.G1920W | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53091320; called by muse, varscan2
- CEP44 | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56659497; called by muse, mutect2, varscan2
- CHST5 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396987418, COSV60339654; called by muse, mutect2, varscan2
- CIB3 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV54166500; called by muse, mutect2, varscan2
- CNTNAP4 | c.1595A>T p.Q532L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56683145; called by muse, mutect2, varscan2
- COL22A1 | c.480C>A p.D160E | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.8); PolyPhen benign (0.012); catalogued as COSV57339352, COSV57348952; called by muse, varscan2
- COL2A1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV61531163; called by muse, mutect2, varscan2
- COPB2 | c.2190G>C p.M730I | Missense Mutation (SNP) | VAF 175/875 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV60350279; called by muse, mutect2, varscan2
- CUL1 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV57386537, COSV57387767; called by muse, mutect2
- CUL4B | c.2047A>T p.T683S | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as COSV60687892; called by muse, mutect2, varscan2
- CXorf56 | c.445G>A p.D149N (on ENST00000536133 / NM_001170570.2; = p.D163N on NM_022101.4) | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV100233349; called by muse, mutect2
- DCBLD2 | c.2212G>A p.G738R | Missense Mutation (SNP) | VAF 200/549 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV54581775; called by muse, mutect2, varscan2
- DDR2 | c.1635G>T p.M545I | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV63371483; called by muse, mutect2, varscan2
- DEPDC5 | c.188A>G p.Q63R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as COSV56699104; called by muse, mutect2, varscan2
- DIS3 | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV66706717; called by muse, mutect2, varscan2
- DNAJB8 | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59878838; called by muse, varscan2
- DPP4 | c.887+1G>C p.X296_splice | Splice Site (SNP) | VAF 19/74 reads (26%) | catalogued as rs761173556, COSV100858738; called by muse, mutect2, varscan2
- DPP6 | c.1440C>G p.I480M (on ENST00000377770 / NM_001364500.2; = p.I418M on NM_001936.5) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59617046; called by muse, mutect2, varscan2
- DRD5 | c.1209C>A p.H403Q | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100431618; called by muse, mutect2, varscan2
- DSP | c.3797A>T p.Q1266L | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV65793167; called by muse, mutect2, varscan2
- ECE1 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51665400; called by muse, mutect2
- ELMO1 | c.549+1G>A p.X183_splice | Splice Site (SNP) | VAF 33/59 reads (56%) | catalogued as COSV100163717; called by muse, mutect2, varscan2
- EPB41L2 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 182/667 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV61355923; called by muse, mutect2, varscan2
- EPB41L3 | c.874A>G p.K292E | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV59455530; called by muse, mutect2, varscan2
- EVI5 | c.1751A>T p.K584I | Missense Mutation (SNP) | VAF 110/271 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV64827464; called by muse, mutect2, varscan2
- EXD1 | c.1130T>A p.V377E | Missense Mutation (SNP) | VAF 136/374 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs773636600, COSV59254397; called by muse, mutect2, varscan2
- FAM155B | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV52936348; called by muse, mutect2, varscan2
- FAT1 | c.11202C>G p.F3734L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101499348, COSV71674423; called by muse, mutect2, varscan2
- FCGBP | c.8593G>A p.V2865M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); catalogued as rs1213694320; called by muse, mutect2, varscan2
- FCN1 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100878838; called by muse, mutect2
- FGD2 | c.128G>T p.C43F | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.011); catalogued as COSV51463906; called by muse, mutect2, varscan2
- FRMPD3 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV52191075; called by muse, mutect2, varscan2
- GPR158 | c.1008G>A p.E336= | Splice Region (SNP) | VAF 42/129 reads (33%) | catalogued as COSV66271556; called by muse, mutect2, varscan2
- GSDME | c.1406T>A p.V469D | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV56039020; called by muse, mutect2, varscan2
- HEATR4 | c.225G>C p.Q75H | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV58573209; called by muse, mutect2, varscan2
- HECTD4 | c.3286G>A p.D1096N | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV61180348; called by muse, mutect2
- HOXC13 | c.844A>C p.S282R | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54498300, COSV54498893; called by muse, mutect2, varscan2
- HTRA1 | c.743A>C p.K248T | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs970437537, COSV64564348; called by muse, mutect2, varscan2
- KALRN | c.2757T>G p.N919K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.995); catalogued as COSV53766412, COSV53782326; called by muse, mutect2, varscan2
- KIAA0319L | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 91/279 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57846222; called by muse, mutect2, varscan2
- KRTAP10-4 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV59964744; called by muse, mutect2
- LAMA4 | c.4447G>A p.E1483K (on ENST00000230538 / NM_001105206.3; = p.E1476K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as COSV100037449, COSV100037828; called by muse, mutect2
- LPCAT1 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs764346932, COSV52038076; called by muse, mutect2
- LRRC8D | c.193A>T p.K65* | Nonsense Mutation (SNP) | VAF 36/97 reads (37%) | catalogued as COSV61579567; called by muse, mutect2, varscan2
- LTBP1 | c.4363G>C p.G1455R (on ENST00000404816 / NM_206943.4; = p.G1129R on NM_000627.4) | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99697962; called by muse, mutect2
- MAGEB6B | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs751620886; called by muse, mutect2, varscan2
- MAN2B2 | c.1787C>A p.T596N | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV53453511; called by muse, mutect2, varscan2
- MAP2 | c.5143C>T p.R1715C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs997102637, COSV52292956; called by muse, mutect2, varscan2
- ME3 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60165047; called by muse, mutect2, varscan2
- MMP9 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63434151; called by muse, mutect2, varscan2
- MUC16 | c.27505T>A p.S9169T | Missense Mutation (SNP) | VAF 99/227 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.981); catalogued as COSV67470281; called by muse, mutect2, varscan2
- MUC16 | c.14270C>G p.P4757R | Missense Mutation (SNP) | VAF 170/471 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.233); catalogued as COSV67470288, COSV67477700; called by muse, mutect2, varscan2
- MYOM1 | c.3841G>C p.E1281Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV55292744; called by muse, mutect2
- N4BP2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs754268777, COSV54702513, COSV54709347; called by muse, mutect2
- NAV3 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 97/264 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV57083589; called by muse, mutect2, varscan2
- NEK4 | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); catalogued as COSV99237282; called by muse, mutect2
- NID1 | c.1740G>A p.V580= | Splice Region (SNP) | VAF 15/67 reads (22%) | catalogued as COSV51621136; called by muse, mutect2, varscan2
- NWD1 | c.4220C>T p.S1407F | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV60343578; called by muse, mutect2, varscan2
- OR2A12 | c.830A>T p.Y277F | Missense Mutation (SNP) | VAF 310/593 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV68821544; called by muse, mutect2
- OR2M4 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 24/412 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100141033; called by muse, mutect2
- OR5AP2 | c.919C>A p.L307I | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV57257778; called by muse, mutect2, varscan2
- OXR1 | c.2237G>C p.G746A (on ENST00000442977 / NM_001198532.1; = p.G718A on NM_018002.3) | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52425625; called by muse, mutect2, varscan2
- PALB2 | c.3335C>T p.P1112L | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV55165689; called by muse, mutect2, varscan2
- PARP9 | c.1338G>C p.L446F | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV100830990; called by muse, mutect2
- PAXBP1 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV51609417; called by muse, mutect2, varscan2
- PCDH18 | c.2420C>G p.T807R | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.942); catalogued as COSV61268869; called by muse, mutect2, varscan2
- PCDHA13 | c.2032G>A p.A678T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV56507720; called by muse, mutect2, varscan2
- PGM2L1 | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV53347250; called by muse, mutect2
- PHLDB2 | c.2890A>T p.M964L (on ENST00000393925 / NM_001134439.2; = p.M921L on NM_145753.2) | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV67311908; called by muse, mutect2, varscan2
- PIAS4 | c.123G>T p.R41S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53679386, COSV53680869; called by muse, mutect2, varscan2
- PIK3C2G | c.4426G>T p.E1476* (on ENST00000676171; = p.E1435* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 48/96 reads (50%) | catalogued as COSV56811550, COSV99851013; called by muse, mutect2, varscan2
- PIWIL3 | c.643A>T p.T215S | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV59995922; called by muse, mutect2, varscan2
- PROKR1 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV58137725; called by muse, mutect2, varscan2
- PTPRT | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 112/164 reads (68%) | catalogued as COSV61970078; called by muse, mutect2
- PXYLP1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 64/252 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1040143705, COSV53890865; called by muse, mutect2, varscan2
- RAB3D | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762283527, COSV55791643; called by muse, mutect2, varscan2
- RALGAPA1 | c.4552G>T p.G1518C | Missense Mutation (SNP) | VAF 80/129 reads (62%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV51884786; called by muse, mutect2, varscan2
- REV3L | c.5177A>T p.E1726V | Missense Mutation (SNP) | VAF 100/278 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV62619508; called by muse, mutect2, varscan2
- RIMS2 | c.2414G>A p.R805Q (on ENST00000666250 / NM_001348490.2; = p.R613Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs538104363, COSV51657124; called by muse, mutect2, varscan2
- RIPOR1 | c.2071C>G p.L691V (on ENST00000379312 / NM_001193522.2; = p.L687V on NM_024519.4) | Missense Mutation (SNP) | VAF 101/300 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV50226501; called by muse, mutect2, varscan2
- RLF | c.3468A>T p.K1156N | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV65652057; called by muse, mutect2, varscan2
- RNASE11 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 128/230 reads (56%) | SIFT tolerated (0.6); PolyPhen benign (0.025); catalogued as COSV60087724; called by muse, mutect2, varscan2
- RNF133 | c.706C>A p.Q236K | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as COSV57365762; called by muse, mutect2
- RUSC2 | c.2041C>G p.L681V | Missense Mutation (SNP) | VAF 81/232 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63428824; called by muse, mutect2, varscan2
- S1PR1 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1425283404, COSV59513419; called by muse, mutect2, varscan2
- SEC31A | c.2923G>C p.G975R (on ENST00000355196 / NM_001318120.1; = p.G936R on NM_016211.4) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs1199559803, COSV52346086; called by muse, mutect2, varscan2
- SESN3 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 97/283 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs746291519, COSV53584099; called by muse, mutect2, varscan2
- SLC22A15 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs375814433; called by muse, mutect2, varscan2
- SLC22A7 | c.949G>C p.E317Q (on ENST00000372585 / NM_153320.2; = p.E315Q on NM_006672.3) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV51484207, COSV51486556; called by muse, mutect2, varscan2
- SLC2A7 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as rs1445881119, COSV68901831; called by muse, mutect2, varscan2
- SLC35C2 | c.809T>A p.L270H | Missense Mutation (SNP) | VAF 61/101 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54757208; called by muse, mutect2, varscan2
- SLC6A14 | c.896C>A p.A299D | Missense Mutation (SNP) | VAF 112/289 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV64147275; called by muse, mutect2, varscan2
- SLIT2 | c.2245C>A p.P749T | Missense Mutation (SNP) | VAF 117/321 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99881864; called by muse, mutect2, varscan2
- SLIT2 | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 116/318 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376329517, COSV56594584; called by muse, mutect2, varscan2
- SMC2 | c.2955G>A p.M985I | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV53956607; called by muse, mutect2, varscan2
- SORL1 | c.3892G>A p.G1298R | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746781563, COSV52749916; called by muse, mutect2, varscan2
- SPATA17 | c.689A>T p.E230V | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV65122483; called by muse, mutect2, varscan2
- SPECC1 | c.699C>A p.N233K | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54958917; called by muse, mutect2, varscan2
- SQSTM1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs758625124, COSV100657685, COSV62434096; called by muse, mutect2, varscan2
- TAAR6 | c.145G>C p.G49R | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745622131, COSV51583818; called by muse, mutect2, varscan2
- TAS1R2 | c.607T>A p.W203R | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64745280; called by muse, mutect2, varscan2
- TEX47 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 95/290 reads (33%) | catalogued as rs1212255745, COSV51878925, COSV51879134; called by muse, mutect2, varscan2
- TGFBR3 | c.2169T>C p.C723= | Splice Region (SNP) | VAF 15/58 reads (26%) | catalogued as COSV53026090; called by muse, mutect2, varscan2
- TMEM217 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 153/409 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.225); catalogued as COSV60825946; called by muse, mutect2, varscan2
- TMPRSS13 | c.1388C>T p.T463I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs777748954, COSV70626427; called by muse, mutect2, varscan2
- TNIK | c.3221G>C p.S1074T | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52683901; called by muse, mutect2, varscan2
- TRIM51 | c.1084T>C p.W362R | Missense Mutation (SNP) | VAF 134/334 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs748684846, COSV55267063; called by muse, mutect2, varscan2
- UBE3C | c.1432T>G p.L478V | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV61953584; called by muse, mutect2, varscan2
- UBN1 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 35/95 reads (37%) | catalogued as COSV52168620; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV51952516; called by muse, mutect2, varscan2
- UTP14A | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.515); catalogued as COSV100928936; called by muse, mutect2
- UTP20 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.434); catalogued as COSV55377676, COSV99881024; called by muse, mutect2
- YES1 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV58850487; called by muse, mutect2, varscan2
- ZBED1 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV58134505; called by muse, mutect2, varscan2
- ZBTB26 | c.672del p.V225Wfs*5 | Frame Shift Del (DEL) | VAF 74/242 reads (31%) | catalogued as COSV65403233; called by mutect2, pindel, varscan2
- ZFHX4 | c.3269A>G p.E1090G | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV50889904; called by muse, mutect2
- ZNF700 | c.992A>G p.K331R | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV54312820; called by muse, mutect2, varscan2
- DHX35 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.011); called by muse, mutect2
- GOLGA3 | c.272del p.P91Lfs*14 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | called by mutect2, varscan2
- HNF1B | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- LGALS8 | c.609del p.G205Efs*3 (on ENST00000341872; = p.G247Efs*3 on NM_006499.4) | Frame Shift Del (DEL) | VAF 27/71 reads (38%) | called by mutect2, pindel, varscan2
- MST1R | c.629G>T p.S210I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2
- MST1R | c.628A>G p.S210G | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); called by muse, mutect2
- ODR4 | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- TEX14 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- TGFBR3 | c.830del p.K277Sfs*6 | Frame Shift Del (DEL) | VAF 75/296 reads (25%) | called by mutect2, pindel, varscan2
- AKAP13 | c.7266A>G p.K2422= (on ENST00000394518 / NM_007200.5; = p.K2426= on NM_006738.6) | Silent (SNP) | VAF 202/572 reads (35%) | catalogued as COSV63460060; called by muse, mutect2, varscan2
- ANKRD29 | c.348G>T p.L116= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV99409068; called by muse, varscan2
- AP1B1 | c.951G>A p.L317= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs1308511990, COSV58018316; called by muse, mutect2, varscan2
- ARPP21 | c.1989C>T p.N663= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as rs550779254, COSV51791188; called by muse, mutect2, varscan2
- BIK | c.426G>A p.L142= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99295612; called by muse, mutect2, varscan2
- BTBD9 | c.75T>C p.H25= | Silent (SNP) | VAF 55/156 reads (35%) | catalogued as rs1467676042, COSV58427182; called by muse, mutect2, varscan2
- CCDC9B | c.1437G>A p.Q479= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV66875528; called by muse, mutect2, varscan2
- CELF4 | c.834A>T p.S278= | Silent (SNP) | VAF 4/7 reads (57%) | catalogued as COSV58454552; called by muse, mutect2
- CELF4 | c.276C>A p.G92= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as COSV58454562; called by muse, mutect2, varscan2
- CLEC16A | c.297G>A p.Q99= | Silent (SNP) | VAF 79/160 reads (49%) | catalogued as COSV68499783; called by muse, mutect2, varscan2
- CMYA5 | c.8577C>T p.S2859= | Silent (SNP) | VAF 140/407 reads (34%) | catalogued as rs770551015, COSV71406304; called by muse, mutect2, varscan2
- CRYBG2 | c.1359C>G p.V453= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs1331654067; called by muse, mutect2, varscan2
- DNAJB8 | c.534G>A p.G178= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV59878846; called by muse, varscan2
- FAM227B | c.615C>A p.S205= | Silent (SNP) | VAF 54/183 reads (30%) | catalogued as COSV54812135; called by muse, mutect2, varscan2
- FCHSD2 | c.1785T>C p.R595= | Silent (SNP) | VAF 55/161 reads (34%) | catalogued as COSV60810337; called by muse, mutect2, varscan2
- GJA4 | c.501A>C p.A167= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV60725422; called by muse, mutect2, varscan2
- H2BC6 | c.57G>A p.V19= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as rs529756458, COSV61591144, COSV61591646; called by muse, mutect2
- IMPG2 | c.2709C>T p.F903= | Silent (SNP) | VAF 102/262 reads (39%) | catalogued as COSV51979291; called by muse, mutect2, varscan2
- IRX5 | c.270A>G p.T90= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV58058978; called by muse, mutect2
- KIAA2026 | c.2466A>G p.E822= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV67355459; called by muse, mutect2, varscan2
- MED12 | c.4935C>A p.T1645= | Silent (SNP) | VAF 46/180 reads (26%) | catalogued as COSV61341752; called by muse, mutect2, varscan2
- MMP9 | c.72C>T p.R24= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100959098, COSV64885788; called by muse, mutect2, varscan2
- MTFMT | c.585G>T p.V195= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as COSV54978096; called by muse, mutect2, varscan2
- MUC16 | c.33954G>A p.V11318= | Silent (SNP) | VAF 218/615 reads (35%) | catalogued as COSV101197815, COSV67470272; called by muse, mutect2, varscan2
- NGEF | c.1407C>T p.S469= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV50925421; called by muse, mutect2, varscan2
- PDGFRA | c.2844G>A p.E948= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV57268875; called by muse, mutect2, varscan2
- PHF24 | c.471C>T p.G157= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as rs1448503859, COSV54274707; called by muse, mutect2, varscan2
- PPRC1 | c.3015C>A p.A1005= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV53385766; called by muse, mutect2, varscan2
- PRKG2 | c.270A>T p.G90= | Silent (SNP) | VAF 61/211 reads (29%) | catalogued as rs1301732117, COSV52324900; called by muse, mutect2, varscan2
- PSAP | c.1050G>T p.P350= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV56467980; called by muse, varscan2
- PSG4 | c.738C>T p.I246= | Silent (SNP) | VAF 12/384 reads (3%) | catalogued as COSV99736581; called by muse, mutect2
- RITA1 | c.621C>T p.V207= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV55321748; called by muse, mutect2, varscan2
- SEC16B | c.2094A>T p.P698= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV57626352; called by muse, mutect2, varscan2
- SHD | c.630C>T p.G210= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV73378730; called by muse, mutect2, varscan2
- SIDT1 | c.246G>C p.V82= | Silent (SNP) | VAF 9/174 reads (5%) | catalogued as COSV53500563, COSV99333344; called by muse, mutect2
- TDRKH | c.468C>T p.A156= | Silent (SNP) | VAF 63/164 reads (38%) | catalogued as COSV64316365; called by muse, mutect2, varscan2
- TRPC7 | c.876C>T p.N292= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as rs574852917, COSV61452561; called by muse, mutect2, varscan2
- USP24 | c.5688C>G p.R1896= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV53768903; called by muse, mutect2, varscan2
- USP35 | c.696C>A p.A232= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV71572927; called by muse, mutect2
- VWF | c.4290G>A p.K1430= | Silent (SNP) | VAF 63/173 reads (36%) | catalogued as COSV54622275; called by muse, mutect2, varscan2
- APOL1 | c.-6A>C | 5'UTR (SNP) | VAF 14/61 reads (23%) | catalogued as COSV59869139; called by muse, mutect2, varscan2
- CTSL3P | n.482G>A | RNA (SNP) | VAF 44/126 reads (35%) | called by muse, mutect2, varscan2
- OR2U1P | n.309G>C | RNA (SNP) | VAF 11/355 reads (3%) | called by muse, mutect2
- PGAP2 | c.165+6098C>T | Intron (SNP) | VAF 16/45 reads (36%) | catalogued as COSV53465508; called by muse, mutect2, varscan2
- SLC7A2 | c.1195+268T>C | Intron (SNP) | VAF 71/179 reads (40%) | catalogued as COSV99134459; called by muse, mutect2, varscan2
